Gene-level copy-number profile of tumor specimen TCGA-V1-A9OX-01A from TCGA case TCGA-V1-A9OX, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9OX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.f7b55d2b-9c90-4cb8-8839-2615290bd861.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V1-A9OX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/de243ed2-b7bd-4761-a499-3c7bd5ba2914

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 5,990; copy number 2: 50,776; copy number 3: 3,014.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V1-A9OX-01A-11D-A41J-01): tumor purity 0.44, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:100,153,672–101,582,128, 11 genes: RNU6-1119P, AC113385.3, AC113385.2, AC113385.1, AC021086.1, FAM174A, AC027315.1, RN7SKP62, ST8SIA4, MIR548P, RN7SL802P.
- chr6:83,067,666–83,857,515, 10 genes: DOP1A, PGM3, RWDD2A, ME1, AL391416.1, PRSS35, SNAP91, AL136972.1, AL139232.1, RIPPLY2.
- chr13:74,828,553–75,482,169, 7 genes (within-gene range 0–1): RIOK3P1, RNU6-38P, SSR1P2, CTAGE11P, LINC01078, TBC1D4, AL139230.1.
- chr13:76,833,839–76,987,943, 7 genes: AL365394.1, KCTD12, AC000403.1, BTF3P11, ACOD1, RPL7P44, DHX9P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,615. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
